Somatic mutation profile of tumor specimen TCGA-AZ-6600-01A (aliquot TCGA-AZ-6600-01A-11D-1771-10) from TCGA case TCGA-AZ-6600, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.6 years (23,581 days).
Specimen TCGA-AZ-6600-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b81c302-5221-4bc2-8e5a-89348762d581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6600-11A (Solid Tissue Normal), aliquot TCGA-AZ-6600-11A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ebc8a09-2223-4e0e-9bf6-b674eaaa94a2

The open-access MAF lists 148 somatic variants for this specimen: 114 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 32, Nonsense Mutation 14, Frame Shift Ins 4, Splice Site 3, RNA 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 32/87 reads (37%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 96/235 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1389C>A p.C463* | Nonsense Mutation (SNP) | VAF 54/92 reads (59%) | hotspot (GDC flag); catalogued as COSV51007044; called by muse, mutect2, varscan2
- TP53 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 82/156 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs745425759, COSV52677009, COSV52679505, COSV53544033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AATK | c.2023C>T p.R675C (on ENST00000326724 / NM_001080395.3; = p.R572C on NM_004920.2) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs775634996, COSV58364837; called by muse, varscan2
- ABCA13 | c.9517A>T p.T3173S | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV101446987; called by muse, mutect2
- ADAMTS5 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs371256284; called by muse, mutect2, varscan2
- ADCY3 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53165174; called by muse, mutect2, varscan2
- AGRN | c.4165C>A p.R1389S | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as COSV65067736, COSV65068188; called by muse, mutect2, varscan2
- APC | c.2108C>A p.A703E | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57328079, COSV99968218, COSV99972153; called by muse, mutect2, varscan2
- APC | c.2767A>T p.R923* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as CM032181, COSV57330257, COSV99972044; called by muse, mutect2, varscan2
- APP | c.2180A>T p.Q727L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60995458; called by muse, mutect2, varscan2
- ARHGAP36 | c.1340C>G p.A447G | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52264796; called by muse, mutect2, varscan2
- ARIH2 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62704086; called by muse, mutect2, varscan2
- ASB3 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.082); catalogued as COSV99712102; called by muse, mutect2, varscan2
- ATP6V1D | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV53598960; called by muse, mutect2, varscan2
- ATP8B3 | c.1183G>C p.V395L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1411637839, COSV59540902; called by muse, mutect2, varscan2
- BAG6 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773367157, COSV99277170; called by muse, mutect2
- C10orf71 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs377090655; called by muse, mutect2, varscan2
- CAPN9 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs375897039; called by muse, mutect2, varscan2
- CC2D2A | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs543650388, COSV67502578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH12 | c.1572C>A p.F524L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66394297; called by muse, mutect2, varscan2
- CDH23 | c.3247A>C p.T1083P | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV99821471; called by muse, mutect2, varscan2
- CDH23 | c.3248C>T p.T1083M | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs756165682, COSV56452031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIR1 | c.1288A>T p.R430* | Nonsense Mutation (SNP) | VAF 147/761 reads (19%) | catalogued as COSV59595406; called by muse, mutect2, varscan2
- CYTH3 | c.389T>C p.V130A | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100641479; called by muse, mutect2, varscan2
- DACH1 | c.1648G>C p.V550L (on ENST00000619232 / NM_001366712.1; = p.V498L on NM_080759.6) | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as rs374225059, COSV57492413; called by muse, mutect2, varscan2
- DGKH | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54928869; called by muse, mutect2, varscan2
- DKK4 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs931955827, COSV55182557; called by muse, mutect2, varscan2
- DNAH10 | c.2879T>C p.I960T (on ENST00000409039; = p.I899T on NM_207437.3) | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV68989546; called by muse, mutect2, varscan2
- DOK3 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758932270, COSV57251301; called by muse, mutect2, varscan2
- DSCAML1 | c.3526C>T p.R1176C (on ENST00000321322; = p.R1116C on NM_020693.4) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261758140, COSV100356200, COSV58390029; called by muse, varscan2
- DSEL | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.999); catalogued as COSV100025724; called by muse, mutect2, varscan2
- EIF2B5 | c.1515G>C p.W505C (on ENST00000647909; = p.W497C on NM_003907.3) | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.464); catalogued as COSV56603910; called by muse, mutect2, varscan2
- ENPEP | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs771608560, COSV54448004, COSV99487702; called by mutect2, varscan2
- ERICH6 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs1385924179, COSV55799277; called by muse, mutect2, varscan2
- FCN2 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52476188; called by muse, mutect2, varscan2
- FLNC | c.3092C>T p.P1031L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs372467579, COSV57952094; called by muse, mutect2, varscan2
- FNDC1 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs771304162, COSV51932431, COSV51939389, COSV51951886; called by muse, mutect2, varscan2
- GPLD1 | c.1652A>G p.Y551C | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV57754949; called by muse, mutect2, varscan2
- GPSM2 | c.219C>G p.F73L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51441502; called by muse, mutect2, varscan2
- GRM5 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs374621808, COSV100550844; called by muse, mutect2, varscan2
- GTF3C5 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs745823251, COSV59599108; called by muse, mutect2, varscan2
- H4C9 | c.228C>A p.H76Q | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs531123491, COSV62889619, COSV62889650; called by muse, mutect2, varscan2
- HAGHL | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV52401129; called by muse, mutect2, varscan2
- HAGHL | c.89T>G p.V30G | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs1179091613, COSV52401138; called by muse, mutect2, varscan2
- HECTD4 | c.8503C>T p.R2835* | Nonsense Mutation (SNP) | VAF 54/234 reads (23%) | catalogued as COSV66388248; called by muse, mutect2, varscan2
- HESX1 | c.541A>T p.T181S | Missense Mutation (SNP) | VAF 119/494 reads (24%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as CM010056, COSV55843049; called by muse, mutect2, varscan2
- HTR7 | c.1158C>A p.F386L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV53284021; called by muse, mutect2, varscan2
- IFNA17 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as COSV69738106; called by muse, mutect2, varscan2
- IGSF5 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66029546; called by muse, mutect2, varscan2
- IKZF4 | c.144C>G p.D48E | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.063); catalogued as COSV56267184, COSV56269605; called by muse, mutect2, varscan2
- IL18BP | c.567T>A p.S189R | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.062); catalogued as COSV52620115; called by muse, mutect2, varscan2
- IPO9 | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55214966; called by muse, mutect2, varscan2
- KCNMB2 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.977); catalogued as rs750828534, COSV64200446; called by muse, mutect2, varscan2
- KLHL38 | c.570T>G p.C190W | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV58086386; called by muse, mutect2, varscan2
- KRTAP19-3 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs543308267, COSV61854565; called by muse, mutect2, varscan2
- LAMA3 | c.3892C>T p.R1298C | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs766625238, COSV58061687; called by muse, mutect2, varscan2
- LGI3 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs749975755, COSV60443084; called by muse, mutect2, varscan2
- LRRC7 | c.328C>T p.R110* (on ENST00000651989 / NM_001370785.2; = p.R77* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 53/134 reads (40%) | catalogued as COSV50415481, COSV50652183; called by muse, mutect2, varscan2
- MAGI2 | c.1474C>G p.L492V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV62639772; called by muse, mutect2, varscan2
- MDN1 | c.15962C>T p.A5321V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as rs1314528074, COSV65518487; called by muse, mutect2, varscan2
- MDN1 | c.5447C>T p.A1816V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV101021445; called by muse, mutect2
- MME | c.882T>A p.N294K | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV100852424; called by muse, mutect2, varscan2
- MON2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs1261726911, COSV99742788; called by muse, mutect2
- MUC17 | c.8612T>G p.L2871* | Nonsense Mutation (SNP) | VAF 22/148 reads (15%) | catalogued as COSV60282407; called by muse, mutect2, varscan2
- MYT1L | c.567C>A p.N189K | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV101220936; called by muse, mutect2, varscan2
- NCKAP5L | c.3761G>A p.R1254Q | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as rs199863130, COSV60128058; called by muse, mutect2, varscan2
- NEB | c.10865A>G p.Q3622R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50844450; called by muse, mutect2, varscan2
- NEUROD6 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 60/324 reads (19%) | catalogued as COSV51770445; called by muse, mutect2, varscan2
- NPBWR1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58695617; called by muse, mutect2, varscan2
- NSFL1C | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 38/181 reads (21%) | catalogued as COSV53792126; called by muse, mutect2, varscan2
- OR14K1 | c.898A>G p.S300G | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99315262; called by muse, mutect2, varscan2
- OR1N1 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as rs563253378, COSV59195166; called by muse, mutect2, varscan2
- OR4D11 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 156/314 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57584961; called by muse, mutect2, varscan2
- OR52E2 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.734); catalogued as COSV100384829; called by muse, mutect2, varscan2
- OR5H1 | c.916A>T p.K306* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV63401916; called by muse, mutect2, varscan2
- PARP14 | c.4244dup p.N1416Efs*19 | Frame Shift Ins (INS) | VAF 14/86 reads (16%) | catalogued as rs1205949740; called by mutect2, varscan2
- PCDH9 | c.2649C>A p.N883K | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.836); catalogued as rs371380403; called by muse, mutect2, varscan2
- PHLPP2 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV100673728; called by muse, mutect2, varscan2
- PKHD1 | c.5225C>T p.T1742M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.572); catalogued as rs372628568; called by muse, mutect2, varscan2
- PRKCQ | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs763773685, COSV54107787; called by muse, mutect2, varscan2
- PRODH2 | c.1013C>T p.P338L (on ENST00000301175; = p.P262L on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs182628111, COSV56560937, COSV99995404; called by muse, mutect2, varscan2
- PTPN14 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 107/507 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100872684; called by muse, mutect2, varscan2
- PYGB | c.1769-2A>T p.X590_splice | Splice Site (SNP) | VAF 97/193 reads (50%) | catalogued as rs775018186, COSV53816401; called by muse, mutect2, varscan2
- RIMS2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755807622, COSV68472575; called by muse, mutect2, varscan2
- ROS1 | c.4718G>A p.S1573N | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.154); catalogued as rs1562291079, COSV63852634, COSV63857133; called by muse, mutect2, varscan2
- RPL3L | c.1030G>T p.V344F | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs746236146, COSV51905630; called by muse, mutect2, varscan2
- RSF1 | c.3691C>T p.R1231* | Nonsense Mutation (SNP) | VAF 96/475 reads (20%) | catalogued as rs867254244, COSV57840953; called by muse, mutect2, varscan2
- RYR2 | c.8190C>A p.D2730E | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.083); catalogued as COSV100770870; called by muse, mutect2, varscan2
- SCN11A | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs764550088, COSV56567140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3D21 | c.2263A>G p.T755A (on ENST00000453908 / NM_001162530.2; = p.T644A on NM_024676.5) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54633664; called by muse, mutect2, varscan2
- SLC9A3 | c.2026_2028del p.K676del | In Frame Del (DEL) | VAF 53/150 reads (35%) | catalogued as rs748285430; called by pindel, varscan2
- SYNE1 | c.20276C>A p.S6759Y (on ENST00000367255 / NM_182961.4; = p.S6688Y on NM_033071.3) | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV99567270; called by muse, mutect2, varscan2
- TAF3 | c.73T>G p.S25A | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.04); catalogued as COSV100720212; called by muse, mutect2, varscan2
- TMEM63A | c.2180A>G p.N727S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV55304807; called by muse, mutect2
- TNS1 | c.3272G>T p.G1091V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.567); catalogued as COSV99410935; called by muse, mutect2, varscan2
- TP53INP2 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs777400598, COSV100873689; called by muse, mutect2, varscan2
- TRIOBP | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV60374905; called by muse, mutect2, varscan2
- TRPC5 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV53286078; called by muse, mutect2, varscan2
- UNC79 | c.5788G>T p.E1930* (on ENST00000393151 / NM_001346218.2; = p.E1753* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 27/202 reads (13%) | catalogued as COSV56378266; called by muse, mutect2, varscan2
- UQCC1 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 56/144 reads (39%) | catalogued as COSV62901999; called by muse, mutect2, varscan2
- WDR7 | c.3724G>C p.G1242R | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54349533; called by muse, mutect2, varscan2
- WNT5A | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52836588; called by muse, mutect2, varscan2
- XPR1 | c.1502-1G>A p.X501_splice | Splice Site (SNP) | VAF 46/251 reads (18%) | catalogued as COSV100851480; called by muse, mutect2, varscan2
- ZC3H12A | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs193053985, COSV100897723; called by muse, mutect2, varscan2
- ZFHX3 | c.4595A>G p.N1532S | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as rs374743360; called by muse, mutect2, varscan2
- ZNF366 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 107/262 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100574125; called by muse, mutect2, varscan2
- ZNF395 | c.982C>A p.L328M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100733991; called by muse, mutect2
- ZNF442 | c.830A>C p.Y277S | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV54420732; called by muse, mutect2, varscan2
- CR1 | c.5896_5902+23del p.X1966_splice | Splice Site (DEL) | VAF 38/116 reads (33%) | called by pindel, varscan2
- MBD5 | c.936dup p.P313Tfs*4 | Frame Shift Ins (INS) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- NIPBL | c.6659dup p.L2220Ffs*3 | Frame Shift Ins (INS) | VAF 36/216 reads (17%) | called by mutect2, pindel, varscan2
- TBX3 | c.438dup p.A147Sfs*13 | Frame Shift Ins (INS) | VAF 37/177 reads (21%) | called by mutect2, pindel, varscan2
- ABCD2 | c.588G>T p.V196= | Silent (SNP) | VAF 71/199 reads (36%) | catalogued as COSV58056107; called by muse, mutect2, varscan2
- AGMO | c.348T>C p.T116= | Silent (SNP) | VAF 18/272 reads (7%) | catalogued as rs536193303, COSV100694268; called by muse, mutect2
- ARHGAP22 | c.1326G>A p.P442= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs772405650, COSV50934357; called by muse, mutect2, varscan2
- ATP7B | c.2103C>A p.I701= | Silent (SNP) | VAF 45/209 reads (22%) | catalogued as COSV54436061; called by muse, mutect2, varscan2
- COL9A1 | c.2403C>T p.P801= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as rs759764758, COSV57880373; called by muse, mutect2, varscan2
- CR1 | c.2700C>T p.C900= | Silent (SNP) | VAF 46/498 reads (9%) | catalogued as rs374989718, COSV65456571; called by muse, mutect2, varscan2
- CYBB | c.1158G>A p.A386= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs374511592, COSV66084935; ClinVar: benign; called by muse, mutect2, varscan2
- ETS1 | c.717G>T p.G239= | Silent (SNP) | VAF 41/207 reads (20%) | catalogued as COSV60092260; called by muse, mutect2, varscan2
- EXD3 | c.891G>A p.P297= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as rs539438670, COSV100573486, COSV59804831; called by muse, mutect2, varscan2
- FAT4 | c.1008C>T p.R336= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV67882519; called by muse, mutect2, varscan2
- GOLGA4 | c.2229C>T p.H743= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs929197586, COSV62709671; called by muse, mutect2, varscan2
- GPR39 | c.1092G>A p.S364= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1396532283, COSV61415924; called by muse, mutect2, varscan2
- IRX4 | c.630G>A p.P210= | Silent (SNP) | VAF 46/247 reads (19%) | catalogued as rs763072295, COSV51471275; called by muse, mutect2, varscan2
- MAGEA12 | c.90T>C p.A30= | Silent (SNP) | VAF 65/205 reads (32%) | catalogued as COSV63294307; called by muse, mutect2, varscan2
- NLRP8 | c.465G>A p.S155= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs1044542565, COSV52592119; called by muse, mutect2, varscan2
- OPLAH | c.1971C>T p.P657= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs1373642781, COSV70677314; called by muse, mutect2, varscan2
- OR4C46 | c.117A>G p.G39= | Silent (SNP) | VAF 41/218 reads (19%) | catalogued as COSV60219545; called by muse, mutect2, varscan2
- OR4K1 | c.432T>C p.F144= | Silent (SNP) | VAF 120/278 reads (43%) | catalogued as COSV53459176; called by muse, mutect2, varscan2
- OR51F2 | c.78G>A p.Q26= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as rs374083836; called by muse, mutect2, varscan2
- OR5T1 | c.600T>G p.S200= | Silent (SNP) | VAF 42/671 reads (6%) | catalogued as COSV100478902, COSV57301674, COSV57301917; called by muse, mutect2
- PHACTR3 | c.792C>T p.A264= | Silent (SNP) | VAF 54/176 reads (31%) | catalogued as rs755553999, COSV63025861; called by muse, mutect2, varscan2
- RNF220 | c.852G>A p.T284= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs369684385; called by muse, mutect2, varscan2
- ROBO2 | c.372G>A p.A124= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs763736763, COSV59901240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINE2 | c.732G>T p.L244= | Silent (SNP) | VAF 58/177 reads (33%) | catalogued as COSV51456281; called by muse, mutect2, varscan2
- SYNE1 | c.20277C>A p.S6759= (on ENST00000367255 / NM_182961.4; = p.S6688= on NM_033071.3) | Silent (SNP) | VAF 56/254 reads (22%) | catalogued as COSV54927755; called by muse, mutect2, varscan2
- TAS2R39 | c.381T>C p.F127= | Silent (SNP) | VAF 107/351 reads (30%) | catalogued as COSV71470827; called by muse, mutect2, varscan2
- TBC1D2 | c.762C>G p.A254= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as COSV59783378; called by muse, mutect2, varscan2
- TMEM215 | c.63C>T p.L21= | Silent (SNP) | VAF 147/457 reads (32%) | catalogued as rs139494754, COSV61363233; called by muse, mutect2, varscan2
- TNIK | c.9C>T p.S3= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV52676245; called by muse, mutect2, varscan2
- USP39 | c.786C>T p.I262= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as COSV100083890, COSV60380595; called by muse, mutect2
- XPO6 | c.2835G>A p.T945= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs768661455, COSV58964242; called by muse, mutect2, varscan2
- ZNF804A | c.411C>T p.F137= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV56439365; called by muse, mutect2, varscan2
- DCHS2 | n.8100G>A | RNA (SNP) | VAF 13/84 reads (15%) | catalogued as rs746831021, COSV100601887; called by muse, mutect2, varscan2
- MIF4GD | c.82+701G>A | Intron (SNP) | VAF 36/68 reads (53%) | catalogued as rs777781853, COSV55453011, COSV99821672; called by muse, mutect2, varscan2
